Somatic mutation profile of tumor specimen 0DNJB6 from CCDI case PBBYFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myxoid liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 14.0 years (5,131 days).
Specimen 0DNJB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4631caac-1e02-4389-8f0e-7721508bcb69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc896f26-18e7-4450-82fe-fa1fa89c4a62

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MIA3 | c.1477A>T p.M493L | Missense Mutation (SNP) | VAF 190/559 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100719566; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 54/1142 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- IFNA16 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 255/734 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OR7C2 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 337/998 reads (34%) | called by muse, mutect2, varscan2
- RBBP8 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 259/793 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- BDKRB2 | c.-21C>T | 5'UTR (SNP) | VAF 264/897 reads (29%) | catalogued as rs759067342; called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 50/456 reads (11%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
